Somatic mutation profile of tumor specimen MP2PRT-PAPIDY-TMP1-A (aliquot MP2PRT-PAPIDY-TMP1-A-1-0-D-A83M-36) from MP2PRT case MP2PRT-PAPIDY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.5 years (918 days).
Specimen MP2PRT-PAPIDY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1f11de8-76b6-456b-8070-c44c39fa3202.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPIDY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPIDY-NB1-A-1-0-D-A83M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c11cce6-3145-4c27-bf55-878775dc7dc7

The open-access MAF lists 22 somatic variants for this specimen: 17 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 3, Frame Shift Del 2, Intron 2, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 148/354 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs121918464, COSV61004751, COSV61004889; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CACNA1E | c.3362G>A p.R1121H | Missense Mutation (SNP) | VAF 134/417 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.223); catalogued as rs370899738; called by muse, mutect2, varscan2
- ESRRG | c.640A>G p.I214V | Missense Mutation (SNP) | VAF 84/194 reads (43%) | SIFT tolerated (0.74); PolyPhen benign (0.013); catalogued as rs772791297; called by muse, mutect2, varscan2
- FGD3 | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 92/308 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.19); catalogued as rs749584174, COSV61599267; called by muse, mutect2, varscan2
- OCM2 | c.90C>G p.F30L | Missense Mutation (SNP) | VAF 82/283 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57535180, COSV57535286; called by muse, mutect2, varscan2
- ETV6 | c.1102T>C p.F368L | Missense Mutation (SNP) | VAF 134/320 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HMCN1 | c.2532C>G p.I844M | Missense Mutation (SNP) | VAF 76/250 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HOXA7 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 156/474 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGKV2-30 | c.356_357del p.W119Sfs*? | Frame Shift Del (DEL) | VAF 31/105 reads (30%) | called by pindel*, varscan2
- KPNA5 | c.1163A>G p.E388G | Missense Mutation (SNP) | VAF 14/297 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.137); called by muse, mutect2
- LMO7 | c.3097A>G p.T1033A (on ENST00000357063; = p.T714A on NM_005358.5) | Missense Mutation (SNP) | VAF 98/232 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- NAV3 | c.1652C>G p.S551C | Missense Mutation (SNP) | VAF 192/430 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.188); called by muse, mutect2
- NEFL | c.1591G>T p.E531* | Nonsense Mutation (SNP) | VAF 131/328 reads (40%) | called by muse, varscan2
- PRXL2C | c.502G>C p.D168H | Missense Mutation (SNP) | VAF 109/313 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- UAP1 | c.421G>C p.E141Q | Missense Mutation (SNP) | VAF 153/354 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- UBA2 | c.37G>T p.E13* | Nonsense Mutation (SNP) | VAF 110/350 reads (31%) | called by muse, mutect2, varscan2
- ZMYM2 | c.1759del p.C587Vfs*33 | Frame Shift Del (DEL) | VAF 68/180 reads (38%) | called by mutect2, pindel, varscan2
- WDR35 | c.747G>A p.L249= | Silent (SNP) | VAF 74/214 reads (35%) | called by muse, mutect2, varscan2
- WDR43 | c.813C>G p.V271= | Silent (SNP) | VAF 84/258 reads (33%) | called by muse, mutect2, varscan2
- ZFHX3 | c.1941G>A p.T647= | Silent (SNP) | VAF 220/430 reads (51%) | catalogued as rs963243958; called by muse, mutect2, varscan2
- IKZF1 | c.161-8201C>A | Intron (SNP) | VAF 20/228 reads (9%) | catalogued as COSV58786716; called by muse, mutect2
- THSD4 | c.-80+14299A>T | Intron (SNP) | VAF 146/383 reads (38%) | called by muse, mutect2, varscan2
